Surgical pathology report (de-identified scan), TCGA case TCGA-VP-A87K, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Washington University, specimen TCGA-VP-A87K-01A (Primary Tumor).

[page 1 of 5]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

ICD-O-3
Adenocarcinoma, acinar + duct
8500/3
Site: Prostate NOS
Q61.9
JW 11/21/13

SURGICAL PATHOLOGY REPORT

FINAL

Patient Name: [REDACTED]
Address: [REDACTED] Service: [REDACTED] Location: [REDACTED] Accession #: [REDACTED]
Gender: M MRN: [REDACTED]
DOB: [REDACTED] Hospital #: [REDACTED] Patient Type: [REDACTED]
Physician(s): [REDACTED]

DIAGNOSIS:

LYMPH NODES, BILATERAL PELVIC, DISSECTION

- TWELVE LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY (0/12)

PROSTATE, RADICAL PROSTATECTOMY

- ADENOCARCINOMA, GLEASON GRADE 4 + 4 = SCORE OF 8, WITH DUCTAL FEATURES
- 54% OF THE PROSTATE IS INVOLVED BY CARCINOMA
- CARCINOMA INVOLVES ALL FOUR QUADRANTS OF THE PROSTATE
- NON-FOCAL EXTRAPROSTATIC EXTENTION BY CARCINOMA PRESENT AT LEFT BASE AND RIGHT

BASE

- RIGHT DISTAL APICAL MARGIN INVOLVED BY CARCINOMA, 1 MM IN LENGTH
- PERIPHEPHAL AND BLADDER NECK MARGINS ARE NEGATIVE FOR TUMOR
- SEE SYNOPSIS

SEMINAL VESICLES, BILATERAL, ROBOTIC-ASSISTED LAPAROSCOPIC PROSTATECTOMY

- CARCINOMA INVOLVES BILATERAL SEMINAL VESICLES

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides and/or other material indicated in the diagnosis.

***Report Electronically Re

Intraoperative Consultation:

Brought to frozen section a "prostate" consisting of a 47.2 grams, 5.0x4.0x3.5 cm prostate gland. Right seminal vesicle measures 2.5 x 1.5 x 0.6 cm, left seminal vesicle measures 2.6 x 1.6 x 0.5 cm. Inked black. Tissue taken for tumor bank (right 518, left 517). Rest for permanents. By

[page 2 of 5]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a [REDACTED] year-old man with localized prostate cancer. Operative procedure: A robotic-assisted laparoscopic prostatectomy.

Specimen(s) Received:

A: LYMPH NODE, BILATERAL PELVIC
B: PROSTATE

Gross Description:

The specimens are received in two formalin-filled containers, each labeled [REDACTED]. The first container is labeled "bilateral pelvic lymph nodes." It contains multiple fragments of adipose tissue, ranging in size from 2.0 x 1.0 x 1.0 cm to 5.5 x 2.0 x 1.0 cm. Multiple lymph nodes are dissected and submitted as follows: Cassette A1 - contains three lymph nodes candidate; A2 and A3 - contains sections of single lymph node; A4 - two lymph nodes candidate; A5 - two lymph nodes candidate; A6 and A7 - serial sections of a single node; A8 and A9 - two lymph node candidates in each block. Jar 1.

The second container is labeled "prostate." It contains a prostate gland that weighs 47 grams, and measures 5.0 x 4.0 x 3.5 cm. Bilateral seminal vesicles are present, with right measuring 2.5 x 1.5 x 0.6 cm and left measuring 2.5 x 1.5 x 0.5 cm. A slit-like defect is present on the posterior surface, measuring 3.0 x 1.5 cm. The urethra is probe-patent. Sectioned to show a tan, nodular, and firm prostatic parenchyma with no discrete lesions identified. Sections are submitted in cassette B1 - contains bladder neck margin; B2 - apical margin, right, radial sections; B3 - apical margin, left, radial sections; B4 - right anterior apex; B5 - right anterior base; B6 to B10 - right posterior apex; B11 to B15 - right posterior base; B16 - right seminal vesicle; B17 - left anterior apex; B18 - left anterior base; B19 to B22 - left posterior apex; B23 to B26 - left posterior base; B27 - left seminal vesicle. Jar 1.

SYNOPTIC WORKSHEET - PROSTATE CARCINOMA

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

The tumor type is adenocarcinoma, mixed ductal and acinar type

INTRAGLANDULAR TUMOR EXTENT

The intraglandular tumor extent (reported as percent of prostate gland involved by carcinoma) = 54%, as determined by a grid morphometric technique

GLEASON'S GRADE

The Gleason's Grade is 4+4 = 8
Tertiary pattern is absent

[page 3 of 5]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

TUMOR LOCATION

The location of the tumor involves the

- right base
- right apex
- left base
- left apex

PERINEURAL INVASION

Perineural Invasion is identified

LYMPH-VASCULAR INVASION

Lymph-Vascular Invasion is not identified

EXTRAPROSTATIC EXTENSION

Extraprostatic (extracapsular) extension is non-focal (established)

The tumor extends into the periprostatic soft tissues (specify site): left base and right base

SEMINAL VESICLES

The tumor extends into the right seminal vesicle wall

The tumor extends into the left seminal vesicle wall

The tumor involves perivesicular soft tissue

SAMPLED SPECIMEN MARGINS

Tumor is present at sampled distal apical (urethral) margin of resection

Total length of positive margins in mm (optional): 1 mm

NON-NEOPLASTIC PROSTATE

The non-neoplastic prostate shows nodular hyperplasia

The non-neoplastic prostate shows PIN, high grade

METASTATIC LYMPH NODES

The lymph nodes are as follows (expressed as the number of metastatic nodes in relation to the total number of nodes examined)

Bilateral pelvic: 0/12

PRIMARY TUMOR (T)

Tumor invades seminal vesicle(s) (T3b)

REGIONAL LYMPH NODES (N)

No regional lymph node metastasis (N0)

DISTANT METASTASIS

No distant metastasis (M0)

STAGE GROUPING

Based on this information, the overall AJCC/UICC stage of the tumor is T3/N0/M0/Gleason score 4+4=8 (Stage III)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Surgical Pathology report is available on-line on

[page 4 of 5]
Patient Name: [REDACTED]

[REDACTED]

Surgical Pathology Report

Final

[REDACTED] SURGICAL PATHOLOGY REPORT [REDACTED]

Page 4 of 4

END OF REPORT

Page: 4 of 4 Printed from

H&A Discrepancy		

[page 5 of 5]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ SS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Gleason score on the initial pathology report is $4+4=8$	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Top slide review Gleason score is $3+4=7$	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The top slide review showed a different Gleason score from the Gleason score on the initial Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature Date

Source: NCI Genomic Data Commons file 70e1ff68-66b5-4635-9e65-97dea96d0642 (TCGA-VP-A87K.6B2C5B8F-61B5-4D8B-A091-B28066A1629A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).